Somatic mutation profile of cancer-model specimen HCM-CSHL-0189-C25-85A (3D Organoid; aliquot HCM-CSHL-0189-C25-85A-01D-A78L-36), derived from the primary tumor of HCMI case HCM-CSHL-0189-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 63.9 years (23,328 days).
Specimen HCM-CSHL-0189-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d026d7f-0e44-418f-938a-cdb0116ef5bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0189-C25-11A (Solid Tissue Normal), aliquot HCM-CSHL-0189-C25-11A-01D-A78L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2e478c8-f825-4114-a8b6-3dd0c0911cbd

The open-access MAF lists 70 somatic variants for this specimen: 43 protein-altering or splice-affecting, 18 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Intron 4, Splice Site 4, RNA 3, In Frame Del 2, Frame Shift Ins 2, 5'Flank 1, 5'UTR 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 146/320 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 79/79 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80338963, CD147870, CM040450, CM041789, CM981228, COSV61683972, COSV61685418, COSV61686083; ClinVar: likely pathogenic / not provided / pathogenic; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 58/106 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768650484, COSV54450847; called by muse, mutect2, varscan2
- AMPH | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.744); catalogued as rs1023213322; called by muse, mutect2, varscan2
- ATM | c.8787-1G>A p.X2929_splice | Splice Site (SNP) | VAF 115/292 reads (39%) | catalogued as CS991313, COSV53759148, COSV53771313; called by muse, mutect2, varscan2
- ATXN7L2 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 55/55 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774200325; called by muse, mutect2, varscan2
- CEP164 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.077); catalogued as rs1296062422, COSV99632759; called by muse, mutect2, varscan2
- DLGAP2 | c.788C>A p.A263E | Missense Mutation (SNP) | VAF 129/273 reads (47%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.482); catalogued as rs375416274, COSV101422983, COSV70099599, COSV99073642; called by muse, mutect2, varscan2
- EID3 | c.583A>T p.M195L | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs750721767; called by muse, mutect2, varscan2
- FCF1 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 62/126 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs771464162, COSV62044420; called by muse, mutect2, varscan2
- HTR3C | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 155/352 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369394644; called by muse, mutect2, varscan2
- IKZF3 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 66/477 reads (14%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as rs1171389897, COSV53105779; called by muse, mutect2, varscan2
- LCE2A | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 144/709 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs201971844; called by muse, mutect2, varscan2
- MISP3 | c.1036dup p.R346Pfs*29 (on ENST00000269720; = p.R204Pfs*29 on NM_001291291.2) | Frame Shift Ins (INS) | VAF 41/190 reads (22%) | catalogued as rs772145225; called by mutect2, varscan2
- MORC2 | c.847C>T p.R283C (on ENST00000397641 / NM_001303256.3; = p.R221C on NM_014941.3) | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765158896, COSV99309970; called by muse, mutect2, varscan2
- MYH4 | c.5585G>A p.R1862H | Missense Mutation (SNP) | VAF 68/68 reads (100%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs538270849, COSV55126101; called by muse, mutect2, varscan2
- NALCN | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1354215007, COSV51942032, COSV51960172; called by muse, mutect2, varscan2
- NOTCH3 | c.5801C>T p.A1934V | Missense Mutation (SNP) | VAF 94/981 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs554059112; called by muse, mutect2
- OR10H2 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 55/272 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs772844697, COSV59946866; called by muse, mutect2, varscan2
- OXTR | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs200253138; called by muse, mutect2, varscan2
- PRPF31 | c.1004C>T p.P335L | Missense Mutation (SNP) | VAF 214/399 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415051331; called by muse, mutect2, varscan2
- PTOV1 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 147/246 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as rs774909974, COSV99681998; called by muse, mutect2, varscan2
- RAC2 | c.502G>A p.V168M | Missense Mutation (SNP) | VAF 196/397 reads (49%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.961); catalogued as COSV50774054; called by muse, mutect2, varscan2
- RASGEF1C | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 41/81 reads (51%) | catalogued as rs1354410922; called by muse, mutect2, varscan2
- SLC16A7 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 98/214 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1370627884; called by muse, mutect2, varscan2
- SSX2IP | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 46/86 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.024); catalogued as rs1299010075; called by muse, mutect2, varscan2
- ADARB2 | c.238_267del p.A80_A89del | In Frame Del (DEL) | VAF 60/170 reads (35%) | called by mutect2, pindel, varscan2
- BRCC3 | c.316-2A>G p.X106_splice | Splice Site (SNP) | VAF 128/128 reads (100%) | called by muse, mutect2, varscan2
- CA1 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 25/477 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- COG4 | c.1481+1G>A p.X494_splice | Splice Site (SNP) | VAF 47/367 reads (13%) | called by muse, mutect2, varscan2
- CPSF1 | c.1930_1935del p.A644_P645del | In Frame Del (DEL) | VAF 30/93 reads (32%) | called by mutect2, pindel, varscan2
- DBN1 | c.1880-7G>A | Splice Region (SNP) | VAF 138/239 reads (58%) | called by muse, mutect2, varscan2
- DMRT2 | c.248dup p.P84Tfs*103 | Frame Shift Ins (INS) | VAF 22/24 reads (92%) | called by mutect2, varscan2
- DNAH7 | c.9557A>C p.Q3186P | Missense Mutation (SNP) | VAF 130/330 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FATE1 | c.106+1G>T p.X36_splice | Splice Site (SNP) | VAF 62/62 reads (100%) | called by muse, mutect2, varscan2
- GLMN | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 160/358 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LARP7 | c.332G>A p.R111K | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- MYOM1 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.201); called by muse, varscan2
- SALL3 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- SETD6 | c.593C>A p.A198D (on ENST00000219315 / NM_001160305.4; = p.A174D on NM_024860.3) | Missense Mutation (SNP) | VAF 116/291 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.636); called by muse, mutect2
- SHQ1 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 9/240 reads (4%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2
- TBP | c.708A>C p.K236N | Missense Mutation (SNP) | VAF 57/112 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF662 | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFAP1 | c.1185C>T p.C395= | Silent (SNP) | VAF 171/443 reads (39%) | catalogued as rs755464157; called by muse, mutect2, varscan2
- APLP1 | c.1281G>A p.T427= | Silent (SNP) | VAF 119/256 reads (46%) | catalogued as rs1177115298; called by muse, mutect2, varscan2
- CPSF3 | c.90C>T p.L30= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as rs143561900; called by muse, mutect2, varscan2
- FOXK1 | c.351C>T p.L117= | Silent (SNP) | VAF 102/210 reads (49%) | catalogued as rs1266818481, COSV100195636; called by muse, mutect2, varscan2
- GAL3ST1 | c.438C>T p.Y146= | Silent (SNP) | VAF 197/401 reads (49%) | catalogued as rs1228915123, COSV58891825; called by muse, mutect2, varscan2
- GREB1 | c.1443G>A p.A481= | Silent (SNP) | VAF 146/300 reads (49%) | catalogued as rs977349859, COSV52193610; called by muse, mutect2, varscan2
- GRIK2 | c.915G>A p.P305= | Silent (SNP) | VAF 66/134 reads (49%) | catalogued as rs145542805, COSV100028502; called by muse, mutect2, varscan2
- HSPG2 | c.12483C>T p.G4161= | Silent (SNP) | VAF 169/169 reads (100%) | called by muse, mutect2, varscan2
- KNDC1 | c.5001C>T p.H1667= | Silent (SNP) | VAF 74/150 reads (49%) | called by muse, mutect2, varscan2
- LAMC1 | c.1812A>G p.V604= | Silent (SNP) | VAF 91/240 reads (38%) | called by muse, mutect2, varscan2
- MTNR1A | c.240G>A p.P80= | Silent (SNP) | VAF 136/461 reads (30%) | catalogued as rs149418383; called by muse, mutect2, varscan2
- OR2T12 | c.759C>A p.G253= | Silent (SNP) | VAF 201/457 reads (44%) | called by muse, mutect2, varscan2
- PCDHB1 | c.279G>A p.E93= | Silent (SNP) | VAF 158/359 reads (44%) | called by muse, mutect2, varscan2
- PRDM9 | c.1827C>T p.V609= | Silent (SNP) | VAF 82/840 reads (10%) | catalogued as rs770444106; called by muse, varscan2
- PRSS56 | c.123G>A p.A41= | Silent (SNP) | VAF 127/224 reads (57%) | catalogued as rs959302495, COSV51323402; called by muse, mutect2, varscan2
- SVEP1 | c.3348G>A p.S1116= | Silent (SNP) | VAF 65/131 reads (50%) | catalogued as rs369614705; called by muse, mutect2, varscan2
- TENM3 | c.7872G>A p.A2624= | Silent (SNP) | VAF 46/85 reads (54%) | catalogued as rs367925910; called by muse, mutect2, varscan2
- UNC5D | c.2235G>T p.G745= | Silent (SNP) | VAF 91/189 reads (48%) | catalogued as COSV54775211; called by muse, mutect2, varscan2
- AC009533.1 | n.805G>T | RNA (SNP) | VAF 134/702 reads (19%) | called by muse, varscan2
- ARHGEF4 | chr2:130916470 G>A | 5'Flank (SNP) | VAF 116/229 reads (51%) | catalogued as COSV58120837, COSV58125529; called by muse, mutect2, varscan2
- CLDND1 | c.-18-217A>T | Intron (SNP) | VAF 74/167 reads (44%) | called by muse, mutect2, varscan2
- DKC1 | c.1260-124A>T | Intron (SNP) | VAF 165/165 reads (100%) | called by muse, mutect2, varscan2
- LNPEP | c.-73C>G | 5'UTR (SNP) | VAF 56/56 reads (100%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.64dup | RNA (INS) | VAF 76/106 reads (72%) | called by mutect2, pindel, varscan2
- NAV3 | c.2024-13005C>T | Intron (SNP) | VAF 85/185 reads (46%) | catalogued as rs867606698, COSV57106168; called by muse, mutect2, varscan2
- OR4C4P | n.632T>G | RNA (SNP) | VAF 11/272 reads (4%) | called by muse, mutect2
- TCTN2 | c.1984+33G>A | Intron (SNP) | VAF 91/197 reads (46%) | called by muse, mutect2, varscan2
